Somatic mutation profile of tumor specimen 0DIKK6 from CCDI case PBBVTU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Rhabdoid tumor, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 0.4 years (142 days).
Specimen 0DIKK6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53c8dc87-40dc-472f-b061-3403a7566f3f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIKJJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c82441b-ceea-4bd3-804b-4fef0b309e5b

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RPE65 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 46/607 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as rs199683808, CM086901, COSV52013336; ClinVar: likely pathogenic; called by muse, mutect2
- DENND4C | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 182/567 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.585); catalogued as COSV71485998; called by muse, mutect2, varscan2
- STXBP5L | c.1390A>G p.I464V | Missense Mutation (SNP) | VAF 80/467 reads (17%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ANKRD18B | c.*64G>T | 3'UTR (SNP) | VAF 12/304 reads (4%) | called by muse, mutect2
- SLC35E2A | n.1178G>T | RNA (SNP) | VAF 90/534 reads (17%) | called by muse, mutect2, varscan2
